Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A4BA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A4BA-01A (Primary Tumor).

Gross Description: Uterus with cervix, upper third of vagina, adnexa uterine, fatty tissue and omentum. The whole area of exocervix and endocervix is replaced by the tumor up to 6.5x4x1.5 cm in size. Endometrium is of normal structure. Ovaries and Fallopian tubes are hyperemic. Fatty tissue fragments are with dense hyperemic lymph nodes up to 1.5 cm in its diameter.

Microscopic Description: Adenocarcinoma of the endocervix with spread on the exocervix, G-2. Tumor size is 6.5x4x1.5 cm. Vagina is of normal structure. Endometrium is hypo-plastic with reactive metaplasia of superficial epithelium. Leiomyoma of the uterus. Ovaries and Fallopian tubes are of normal structure. Four examined lymph nodes from the left side and six lymph nodes from the right side demonstrated reactive changes. Omentum is of normal structure.

Diagnosis Details: Tumor Features: Indeterminate, Tumor Extent: Lesion greater than 4.0cm, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: CERVIX TISSUE CHECKLIST

Specimen type: Simple hysterectomy

Tumor site: Cervix

Tumor size: 4 x 1.5 x 6.5 cm

Histologic type: Adenocarcinoma

Histologic grade: Moderately differentiated

Tumor extent: Lesion greater than 4.0 cm

Lymph nodes: 0/10 positive for metastasis (Pelvic lymph nodes 0/10)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0-3
adenocarcinoma, endocervical type
8384/3
site: cervix, NOS 853.9
JW
9/26/12

Reviewed In:	9/17/12	

Source: NCI Genomic Data Commons file 00316684-4f81-40f2-bd75-0f775aac5fd7 (TCGA-EA-A4BA.E9335EB7-5DF6-4C05-AC5C-FEEC629ED84E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).